Somatic mutation profile of tumor specimen 0DLSXC from CCDI case PBBZKG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.6 years (3,143 days).
Specimen 0DLSXC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dc58281-b002-4ba2-9d5b-744c593d6322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLSX7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fe8c091-950b-4675-ad3d-01d0b6d4647e

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 6, 3'UTR 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LILRA1 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 151/470 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.473); catalogued as rs779716359, COSV52179703; called by muse, mutect2, varscan2
- SBNO1 | c.1057A>G p.N353D (on ENST00000420886; = p.N352D on NM_018183.5) | Missense Mutation (SNP) | VAF 136/379 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99928624; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, varscan2
- SLC5A4 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 174/576 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV56674376; called by muse, mutect2, varscan2
- USP26 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 27/714 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.145); catalogued as COSV63708500; called by muse, mutect2
- ATP11C | c.1194C>A p.D398E | Missense Mutation (SNP) | VAF 160/740 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- C6orf15 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 213/508 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 58/1102 reads (5%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- KCNU1 | c.2470A>T p.I824F | Missense Mutation (SNP) | VAF 270/777 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- TEX13C | c.1982del p.V661Afs*11 | Frame Shift Del (DEL) | VAF 94/722 reads (13%) | called by pindel, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 8/110 reads (7%) | catalogued as rs1262556378; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 56/1001 reads (6%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 50/508 reads (10%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 13/112 reads (12%) | called by muse, varscan2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 12/119 reads (10%) | called by muse, varscan2
- SLFN12L | c.*82_*83insT | 3'UTR (INS) | VAF 6/78 reads (8%) | catalogued as COSV53472193; called by mutect2, pindel
- SPINT2 | c.391+51G>A | Intron (SNP) | VAF 16/136 reads (12%) | catalogued as rs749337905; called by muse, mutect2
- ZAP70 | c.1623+26C>T | Intron (SNP) | VAF 215/564 reads (38%) | catalogued as rs201473420; called by muse, mutect2, varscan2
